TARGET case TARGET-40-NAAHCV — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42f225aa-dc4f-5ac4-a0b3-795145f59428

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 9.0 years (3,295 days); Year of diagnosis: 2006; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 3,389 days (9.3 years); Sites of involvement: Bone, NOS.
   Pathology details: Necrosis percent: 95.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 321 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 321 days; Days to first event: 321 days; First event: Relapse.
- Days to follow up: 3,389 days (9.3 years); Year of follow up: 2015.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHCV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3389
- Protocol: BCM
- Disease at diagnosis: Metastatic
- Metastasis site: Left femur, tibia
- Primary tumor site: Leg/Foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Amputation
- Site of initial relapse: Lung
- Histologic response: Stage 3/4
